Gene-level copy-number profile of tumor specimen C3L-08267-01 from CPTAC case C3L-08267, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.9 years (27,372 days).
Specimen C3L-08267-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Cardia; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2d2ffd4c-2256-4c26-b2fe-a508d1db8fda.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08267-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/d1b00a59-e009-452c-a936-a6025859f861

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 643; copy number 1: 4,113; copy number 2: 28,785; copy number 3: 19,601; copy number 4: 4,310; copy number 5: 382; copy number 6: 1,027; copy number 7: 7; copy number 8: 10; copy number 9: 5; copy number 78: 4; copy number 110: 2; copy number 186: 2; copy number 191: 2; copy number 207: 3; copy number 214: 10; copy number 274: 5; copy number 322: 1.

Homozygous deletions (total copy number 0; autosomes only): 125 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr1:227,482,253–227,561,300, 7 genes: AL451054.2, AL451054.3, TUBB8P10, TUBB8P9, AL451054.1, AL451054.4, RNA5SP77.
- chr4:90,370,123–90,370,427, 1 gene (within-gene range 0–2): RN7SKP248.
- chr4:173,094,868–173,169,652, 2 genes (within-gene range 0–1): AC105285.1, RN7SL253P.
- chr5:59,314,110–59,314,800, 1 gene (within-gene range 0–2): AC008833.1.
- chr7:111,091,006–111,125,454, 1 gene (within-gene range 0–2): LRRN3.
- chr8:12,115,767–12,177,550, 6 genes (within-gene range 0–1): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr12:39,755,025–40,106,089, 1 gene (within-gene range 0–2): SLC2A13.
- chr12:40,068,243–40,068,590, 1 gene (within-gene range 0–2): RPL30P13.
- chr12:74,656,561–74,664,141, 2 genes: AC123904.2, AC123904.1.
- chr13:66,825,169–67,002,007, 3 genes (within-gene range 0–2): PCDH9-AS2, PCDH9-AS3, PCDH9-AS4.
- chr15:20,228,620–21,981,245, 87 genes (broad region; genes not listed).
- chr15:51,341,655–51,408,005, 3 genes (within-gene range 0–2): GLDN, AC020891.4, AC020891.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,460 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,094,987–31,296,788, 5 genes, copy number 6–8: SELENOWP1, AC114495.1, NKAIN1, SNRNP40, AC114495.2.
- chr1:32,247,222–34,277,292, 58 genes, copy number 6: FAM167B, LCK, Metazoa_SRP, Y_RNA, HDAC1, MARCKSL1, AL109945.1, TSSK3, FAM229A, BSDC1, GAPDHP20, AL356986.1, LRRC37A12P, RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1, CSMD2, HSPD1P14, HMGB4, CSMD2-AS1, RNA5SP42, C1orf94, AC115286.1.
- chr1:44,988,234–46,221,256, 42 genes, copy number 5: PPIAP35, MRPS17P1, HECTD3, UROD, ZSWIM5, OSTCP5, LINC01144, HPDL, MUTYH, AL451136.1, TOE1, TESK2, PPIAP36, CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4, CCDC17, GPBP1L1, RPS15AP10, AL604028.2, TMEM69, IPP, AL604028.1, AL603882.1, MAST2, TMA16P2, PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1.
- chr1:47,416,285–47,704,029, 7 genes, copy number 5: FOXE3, FOXD2-AS1, FOXD2, AL356458.1, RPL21P24, ATP6V0E1P4, LINC01738.
- chr1:196,774,813–196,795,407, 1 gene, copy number 5: CFHR3.
- chr3:3,700,814–5,256,761, 25 genes, copy number 5–7 (within-gene range 1–7): SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1.
- chr3:9,498,361–13,283,281, 98 genes, copy number 5 (broad region; genes not listed).
- chr4:48,066,393–49,062,081, 17 genes, copy number 5: TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr8:11,676,959–11,933,203, 10 genes, copy number 214: GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P.
- chr8:54,330,687–54,479,963, 6 genes, copy number 186–274: RNU105C, AC027250.1, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:54,522,799–54,523,297, 1 gene, copy number 274: SEC11B.
- chr8:55,102,028–55,542,054, 1 gene, copy number 78 (within-gene range 1–155): XKR4.
- chr8:55,161,446–55,773,407, 5 genes, copy number 78–191 (within-gene range 1–191): AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265.
- chr8:64,373,151–64,383,787, 2 genes, copy number 110: MIR124-2HG, MIR124-2.
- chr8:126,325,454–126,329,538, 1 gene, copy number 322: AC087667.1.
- chr8:127,578,473–127,742,951, 3 genes, copy number 207: AC104370.1, CASC11, MYC.
- chr11:13,962,723–14,520,344, 8 genes, copy number 6 (within-gene range 4–6): SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2.
- chr11:28,020,619–28,683,469, 9 genes, copy number 6–7: KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758.
- chr12:12,310–38,133, 3 genes, copy number 5: DDX11L8, WASH8P, FAM138D.
- chr12:24,993,424–27,824,382, 72 genes, copy number 6 (broad region; genes not listed).
- chr14:18,333,726–19,714,332, 69 genes, copy number 5 (broad region; genes not listed).
- chr14:21,521,080–21,811,977, 24 genes, copy number 5: SALL2, AL161747.2, RBBP4P5, OR10G3, AC243972.2, OR10G1P, UBE2NP1, TRAV1-1, OR10G2, TRAV1-2, ARL6IP1P1, OR4E2, OR4E1, AC243972.3, TRAV2, AC243972.1, TRAV3, TRAV4, TRAV5, RPL4P1, TRAV6, TRAV7, TRAV8-1, TRAV9-1.
- chr14:22,132,553–22,482,346, 36 genes, copy number 5 (within-gene range 4–5): TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr14:38,034,287–38,194,281, 1 gene, copy number 7 (within-gene range 4–7): AL392023.2.
- chr14:91,271,323–91,780,707, 9 genes, copy number 5 (within-gene range 4–5): CCDC88C, AL133153.2, AL133153.1, PPP4R3A, AL133373.2, AL133373.3, CATSPERB, POLR3GP1, NANOGP7.
- chr14:106,556,936–106,557,477, 1 gene, copy number 5: IGHV3-49.
- chr14:106,583,501–106,583,807, 1 gene, copy number 5 (within-gene range 4–5): IGHV8-51-1.
- chr14:106,609,762–106,879,812, 40 genes, copy number 5: IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr16:75,218,988–75,228,197, 2 genes, copy number 5 (within-gene range 3–5): CTRB1, AC009078.2.
- chr18:21,380,286–21,704,780, 8 genes, copy number 5 (within-gene range 3–5): AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1.
- chr18:21,711,950–21,712,119, 1 gene, copy number 5 (within-gene range 4–5): AC106037.1.
- chr18:22,413,599–23,026,488, 9 genes, copy number 6–9 (within-gene range 3–9): CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2.
- chr19:58,479,512–58,512,413, 1 gene, copy number 8 (within-gene range 3–8): SLC27A5.
- chr19:58,500,505–58,605,223, 13 genes, copy number 6–8: AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr20:30,214,765–64,327,972, 870 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,541. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
